TARGET case TARGET-30-PAIVZR — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c3ce237a-1972-564d-adb4-150a0971cd77

Demographics
Sex at birth: female; Age at index: 3 years; Vital status: Dead; Days to death: 787 days (2.2 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 3.4 years (1,227 days); Year of diagnosis: 1999; Days to last follow up: 787 days (2.2 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Necrosis percent: 35; Percent tumor nuclei: 65.
   Treatment given: Protocol identifier: 9047.

Follow-up (2 entries)
- Days to follow up: 404 days (1.1 years); Days to first event: 404 days (1.1 years); First event: Death.
- Days to follow up: 787 days (2.2 years); Year of follow up: 2001.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAIVZR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIVZR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 787
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- Percent Tumor v/s Stroma: 95/5
